Gene-level copy-number profile of tumor specimen C3N-03420-02 from CPTAC case C3N-03420, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 66.1 years (24,141 days).
Specimen C3N-03420-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 071f371b-9070-4721-9f88-cdf70a20afcf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03420-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/8e5edbb7-3ea8-4f26-9fc8-2f2038791691

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 139; copy number 2: 3,380; copy number 3: 282; copy number 4: 41,408; copy number 5: 4,136; copy number 6: 5,451; copy number 7: 647; copy number 8: 2,461; copy number 9: 174; copy number 10: 2; copy number 12: 313; copy number 14: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 114 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:19,471,296–22,853,344, 15 genes, copy number 9 (within-gene range 3–9): CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12.
- chr5:22,212,476–23,014,527, 4 genes, copy number 9: AC138854.1, GCNT1P2, AC091938.1, AC010445.1.
- chr8:20,934,435–21,298,168, 7 genes, copy number 9 (within-gene range 2–9): TMEM97P2, AC015468.3, AC021613.1, AC015468.1, AC015468.2, LINC02153, AC103719.1.
- chr8:145,047,860–145,066,685, 2 genes, copy number 10: AC139103.1, C8orf33.
- chr14:21,962,819–22,518,871, 85 genes, copy number 9 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 9: TRAC.

Autosomal genes at a single copy (total copy number 1): 139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
